Surgical pathology report (de-identified scan), TCGA case TCGA-M8-A5N4, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-M8-A5N4-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	ductal adenocarcinoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	pancreas
Tumour Size (cm)	3.3999999999999999
Histology	ductal adenocarcinoma
Grade/Differentiation	II
Pathological T	T3
Pathological N	N0
Clinical M	M0
Histology Comments	pancreatic head

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD O-3
Adenocarcinoma, Duct NOS
8500/3
Site: Head of Pancreas
C25D
W 2/11/13

Source: NCI Genomic Data Commons file 71ed1a62-3a3b-43dd-9522-6c96599a1b96 (TCGA-M8-A5N4.DA73BF07-6A4B-472E-8164-486504B8A516.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).